Gene-level copy-number profile of tumor specimen TCGA-HT-7873-01B from TCGA case TCGA-HT-7873, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.6 years (10,805 days).
Specimen TCGA-HT-7873-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.7326ed25-fd02-4bb8-b62d-62ede00da264.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-7873-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2957827-e10b-4e3a-9ddb-30a794fec522

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 5,588; copy number 2: 50,904; copy number 3: 2,306; copy number 4: 350; copy number 5: 496; copy number 6: 94; copy number 7: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-7873-01B-11D-2391-01): tumor purity 0.82, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:19,813,685–19,818,090, 1 gene (within-gene range 0–1): AC004543.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 666 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:2,305,083–25,933,710, 394 genes, copy number 5 (broad region; genes not listed).
- chr12:19,129,752–19,376,400, 1 gene, copy number 6 (within-gene range 3–6): PLEKHA5.
- chr12:19,303,480–25,648,579, 93 genes, copy number 6 (broad region; genes not listed).
- chr13:106,374,477–110,307,157, 50 genes, copy number 5 (within-gene range 3–5): LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1.
- chr19:14,789,260–17,075,625, 127 genes, copy number 5–7 (broad region; genes not listed).
- chr19:17,095,418–17,099,307, 1 gene, copy number 5: AC020908.3.

Autosomal genes at a single copy (total copy number 1): 3,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
